MMRF case MMRF_2225 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/0818bdf7-9c1a-413f-873a-3d6d8fbbe6d7

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 53 years; Vital status: Dead; Days to death: 782 days (2.1 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 53.3 years (19,472 days); ISS stage: II; Days to last known disease status: 782 days (2.1 years); Days to last follow up: 782 days (2.1 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 168 days.
   Treatment given: Therapeutic agents: Bortezomib + Doxorubicin; Regimen or line of therapy: First line of therapy; Days to treatment start: 2 days; Days to treatment end: 165 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 180 days; Days to treatment end: 181 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 183 days; Days to treatment end: 183 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 239 days; Days to treatment end: 270 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 353 days; Days to treatment end: 527 days (1.4 years).
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone + Other; Regimen or line of therapy: Second line of therapy; Days to treatment start: 552 days (1.5 years); Days to treatment end: 555 days (1.5 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Third line of therapy; Days to treatment start: 591 days (1.6 years); Days to treatment end: 592 days (1.6 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Third line of therapy; Days to treatment start: 591 days (1.6 years); Days to treatment end: 635 days (1.7 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 591 days (1.6 years); Days to treatment end: 639 days (1.7 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Third line of therapy; Days to treatment start: 598 days (1.6 years); Days to treatment end: 635 days (1.7 years).
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone + Other; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 648 days (1.8 years); Days to treatment end: 765 days (2.1 years).
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 648 days (1.8 years); Days to treatment end: 675 days (1.8 years).
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 684 days (1.9 years); Days to treatment end: 765 days (2.1 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 782.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 1): M Protein 1.2 g/dL; Immunoglobulin G 3.35 g/L; Immunoglobulin A 9.42 g/L; Immunoglobulin M 0.447 g/L; Beta 2 Microglobulin 3.95 µg/mL; Lactate Dehydrogenase 4.85 µkat/L; Hemoglobin 5.89 mmol/L; Leukocytes 5.81 ×10⁹/L; Absolute Neutrophil 4.92 ×10⁹/L; Platelets 206 ×10⁹/L; Creatinine 116 µmol/L; Albumin 37 g/L; Total Protein 6.7 g/dL; C-Reactive Protein 0.1 mg/dL.
- Day 92 (ECOG 1): M Protein 5.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 18.3 mg/dL; Immunoglobulin G 3.95 g/L; Immunoglobulin A 1.98 g/L; Immunoglobulin M 0.321 g/L; Lactate Dehydrogenase 6.43 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 2.3 ×10⁹/L; Absolute Neutrophil 1.32 ×10⁹/L; Platelets 128 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Total Protein 6.8 g/dL.
- Day 178: Serum Free Immunoglobulin Light Chain, Kappa 0.781 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.93 mg/dL; Immunoglobulin G 3.46 g/L; Immunoglobulin A 1.24 g/L; Immunoglobulin M 0.638 g/L; Lactate Dehydrogenase 5.85 µkat/L; Hemoglobin 8.99 mmol/L; Leukocytes 4.82 ×10⁹/L; Absolute Neutrophil 3.18 ×10⁹/L; Platelets 368 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.63 mmol/L; Albumin 50 g/L; Total Protein 7.1 g/dL.
- Day 260 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.152 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.21 mg/dL; Immunoglobulin G 2.98 g/L; Immunoglobulin A 0.321 g/L; Immunoglobulin M 0.27 g/L; Lactate Dehydrogenase 5.6 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 3.44 ×10⁹/L; Absolute Neutrophil 2.35 ×10⁹/L; Platelets 173 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L.
- Day 365 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 0.272 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 11.3 mg/dL; Immunoglobulin G 3.62 g/L; Immunoglobulin A 0.824 g/L; Immunoglobulin M 0.291 g/L; Lactate Dehydrogenase 5.58 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 3.94 ×10⁹/L; Absolute Neutrophil 2.62 ×10⁹/L; Platelets 142 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 5.71 mmol/L.
- Day 449: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.64 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.3 mg/dL; Immunoglobulin G 2.07 g/L; Immunoglobulin A 0.298 g/L; Immunoglobulin M 0.345 g/L; Lactate Dehydrogenase 7.78 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 4.21 ×10⁹/L; Absolute Neutrophil 2.69 ×10⁹/L; Platelets 227 ×10⁹/L; Creatinine 87.5 µmol/L; Total Protein 5.8 g/dL.
- Day 549: M Protein 0.79 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.292 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 149 mg/dL; Immunoglobulin G 2.78 g/L; Immunoglobulin A 5.1 g/L; Immunoglobulin M 0.205 g/L; Beta 2 Microglobulin 3.08 µg/mL; Hemoglobin 7.13 mmol/L; Leukocytes 15.9 ×10⁹/L; Absolute Neutrophil 3.76 ×10⁹/L; Platelets 56 ×10⁹/L; Creatinine 171 µmol/L; Calcium 3.2 mmol/L.
- Day 639: M Protein 0.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.073 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 201 mg/dL; Immunoglobulin G 2.5 g/L; Immunoglobulin A 2.5 g/L; Immunoglobulin M 0.138 g/L; Beta 2 Microglobulin 5.47 µg/mL; Lactate Dehydrogenase 6.28 µkat/L; Hemoglobin 5.39 mmol/L; Leukocytes 2.44 ×10⁹/L; Absolute Neutrophil 0.764 ×10⁹/L; Platelets 20 ×10⁹/L; Creatinine 93.7 µmol/L.
- Day 716 (ECOG 2): Serum Free Immunoglobulin Light Chain, Kappa 0.188 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 269 mg/dL; Immunoglobulin G 1.04 g/L; Immunoglobulin A 3.76 g/L; Immunoglobulin M 0.096 g/L; Hemoglobin 4.4 mmol/L; Leukocytes 2.3 ×10⁹/L; Absolute Neutrophil 0.9 ×10⁹/L; Platelets 28 ×10⁹/L; Creatinine 82.2 µmol/L; Total Protein 6.4 g/dL; Glucose 4.07 mmol/L.

Other clinical attributes
- Day 1: Weight: 65 kg; Height: 157 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2225_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_2225_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
